Somatic mutation profile of tumor specimen MP2PRT-PARNGY-TMP1-A (aliquot MP2PRT-PARNGY-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PARNGY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.7 years (2,081 days).
Specimen MP2PRT-PARNGY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ef89cae-29da-42d1-a4bb-b765ae8214ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARNGY-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARNGY-NM1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58395b8d-ac40-49dc-8316-8f761edbbbae

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, Frame Shift Del 1, RNA 1, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP17A | c.2027G>A p.R676H | Missense Mutation (SNP) | VAF 42/1045 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.32); catalogued as rs774253177; called by muse, mutect2
- HSPA12B | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 178/512 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs778322208; called by muse, mutect2, varscan2
- LRRC9 | c.2573G>A p.R858Q | Missense Mutation (SNP) | VAF 97/330 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as rs1410473447; called by muse, mutect2, varscan2
- XIRP2 | c.6680C>T p.S2227L (on ENST00000628543; = p.S2402L on NM_152381.6) | Missense Mutation (SNP) | VAF 20/572 reads (3%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1176103463; called by muse, mutect2
- CNTN6 | c.1364+1del | Frame Shift Del (DEL) | VAF 22/252 reads (9%) | called by mutect2, pindel
- IGHV1-69 | c.350_351insGGCGAG p.A116_R117dup | In Frame Ins (INS) | VAF 9/28 reads (32%) | called by pindel, varscan2
- IGHV4-59 | chr14:106627243 ACTGTGTCTCT>TCTCTCTC | Missense Mutation (DEL) | VAF 128/331 reads (39%) | called by pindel, varscan2*
- ZNF74 | c.1281_1282insTA p.R428Yfs*184 | Frame Shift Ins (INS) | VAF 247/608 reads (41%) | called by mutect2, pindel*, varscan2
- ASXL3 | c.4482A>G p.S1494= | Silent (SNP) | VAF 187/491 reads (38%) | called by muse, mutect2, varscan2
- IGLV4-60 | chr22:22162680 del CACA | Silent (DEL) | VAF 8/76 reads (11%) | called by pindel, varscan2
- LGALS9 | c.549C>T p.G183= (on ENST00000395473 / NM_009587.3; = p.G151= on NM_002308.4) | Silent (SNP) | VAF 176/532 reads (33%) | catalogued as rs778479727; called by muse, mutect2, varscan2
- TMEM132C | c.2397C>T p.F799= | Silent (SNP) | VAF 175/388 reads (45%) | catalogued as rs772670945, COSV59429724; called by muse, mutect2, varscan2
- AL121718.1 | n.316C>A | RNA (SNP) | VAF 23/145 reads (16%) | called by muse, mutect2, varscan2
